Somatic mutation profile of tumor specimen PCProject_0410_T1_WES (aliquot PCProject_0410_T1_WES_1) from CMI case PCProject_0410, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.0 years (24,819 days).
Specimen PCProject_0410_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5640d699-d577-4eb2-99bf-698e3f2479da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0410_SALIVA (DNA), aliquot PCProject_0410_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d81a432b-4d97-4780-8f77-b255f86accec

The open-access MAF lists 65 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, Intron 8, 3'UTR 4, Frame Shift Del 3, 3'Flank 2, 5'UTR 2, Splice Region 2, RNA 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 66/343 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1996A>G p.K666E | Missense Mutation (SNP) | VAF 60/217 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754688962, COSV59206172, COSV59206856; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.114); catalogued as rs758984872, COSV68067524; called by muse, mutect2, varscan2
- BCAS4 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.051); catalogued as rs1050513716; called by muse, mutect2, varscan2
- DNAH3 | c.10426C>T p.L3476F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs762661332; called by mutect2, varscan2
- GLB1L3 | c.1782C>T p.N594= | Splice Region (SNP) | VAF 6/78 reads (8%) | catalogued as rs911960109; called by muse, mutect2
- IRX6 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs377555554, COSV99306148; called by muse, mutect2, varscan2
- KCNH1 | c.480C>A p.S160R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV55069632, COSV55090729; called by muse, varscan2
- MYF5 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57357005; called by muse, mutect2, varscan2
- NHSL1 | c.676+3A>G | Splice Region (SNP) | VAF 14/65 reads (22%) | catalogued as COSV58675879; called by muse, mutect2
- OR7C2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as rs1291390751; called by muse, mutect2, varscan2
- RASA3 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 43/166 reads (26%) | catalogued as rs781295846, COSV61871133; called by muse, mutect2, varscan2
- SEL1L2 | c.1916C>T p.T639M | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs754101601, COSV53158821; called by muse, varscan2
- SORCS2 | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs767510315, COSV61172491; called by muse, mutect2, varscan2
- SPATA17 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145142638; called by muse, mutect2, varscan2
- TSGA10 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs923653988, COSV100747696, COSV61824855; called by muse, mutect2, varscan2
- WAPL | c.2803G>A p.G935R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.117); catalogued as COSV53940382; called by muse, mutect2
- XIRP2 | c.9884C>G p.S3295C (on ENST00000628543; = p.S3470C on NM_152381.6) | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54740048; called by muse, mutect2, varscan2
- ADCY5 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AIG1 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- GASK1B | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- GDF10 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GPS2 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- MVP | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFXL1 | c.2087del p.P696Qfs*16 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, varscan2
- PLD1 | c.1357C>G p.H453D | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- PRAME | c.196A>C p.S66R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRAME | c.195C>A p.H65Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RCC1L | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RNASEL | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- TRDN | c.1649del p.K550Rfs*16 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- UPK3A | c.19del p.L7Cfs*13 | Frame Shift Del (DEL) | VAF 89/380 reads (23%) | called by mutect2, pindel, varscan2
- WHRN | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 100/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- APOA5 | c.681C>T p.C227= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- BTAF1 | c.3735G>A p.E1245= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV56431493; called by muse, mutect2
- DOP1A | c.2907C>T p.L969= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs377295029; called by mutect2, varscan2
- GPS2 | c.552T>G p.P184= | Silent (SNP) | VAF 23/237 reads (10%) | called by muse, mutect2
- GRIP2 | c.2001C>T p.I667= (on ENST00000619221; = p.I570= on NM_001080423.4) | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as rs1250838605; called by muse, mutect2, varscan2
- NOL10 | c.1440C>T p.L480= | Silent (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.225C>T p.F75= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV54053472; called by mutect2, varscan2
- PHACTR3 | c.432G>A p.S144= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as rs768581399, COSV63027519; called by muse, mutect2, varscan2
- PPIP5K2 | c.849T>A p.P283= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs1554210450; called by muse, mutect2, varscan2
- PTCD3 | c.15T>C p.S5= | Silent (SNP) | VAF 82/375 reads (22%) | catalogued as rs759112070; called by muse, mutect2, varscan2
- SLC9A3 | c.75C>T p.A25= | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2
- SPNS1 | c.777G>A p.S259= | Silent (SNP) | VAF 11/162 reads (7%) | catalogued as rs1567525247; called by muse, mutect2
- WDR13 | c.1296C>T p.C432= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs369636679, COSV54331960; called by mutect2, varscan2
- ZFHX4 | c.7308G>A p.S2436= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as rs778251008, COSV50786796, COSV99263090; called by muse, varscan2
- AC021218.1 | n.380G>A | RNA (SNP) | VAF 6/38 reads (16%) | catalogued as rs1224712645; called by mutect2, varscan2
- ARHGAP9 | c.-179G>C | 5'UTR (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- CNOT1 | c.6453+418T>C | Intron (SNP) | VAF 10/66 reads (15%) | catalogued as rs1372199456; called by muse, varscan2
- EP300 | c.2054-38G>A | Intron (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- EPS15 | c.561+2509A>G | Intron (SNP) | VAF 12/286 reads (4%) | catalogued as rs903125548; called by muse, mutect2
- FAM161A | c.*755G>A | 3'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as rs933044250; ClinVar: uncertain significance; called by muse, varscan2
- KHDC3L | c.-10C>T | 5'UTR (SNP) | VAF 6/52 reads (12%) | catalogued as COSV64869120; called by mutect2, varscan2
- LRR1 | chr14:49598638 G>T | 5'Flank (SNP) | VAF 105/389 reads (27%) | called by muse, mutect2, varscan2
- MIA2 | c.249+197T>C | Intron (SNP) | VAF 6/49 reads (12%) | catalogued as rs1226144134; called by muse, varscan2
- NDUFS8 | c.373-493T>C | Intron (SNP) | VAF 8/92 reads (9%) | catalogued as rs1331518962; called by muse, mutect2
- ODAPH | c.*86C>T | 3'UTR (SNP) | VAF 16/64 reads (25%) | catalogued as rs192831647, COSV100290178; called by muse, mutect2, varscan2
- ORC6 | c.*258A>G | 3'UTR (SNP) | VAF 10/72 reads (14%) | called by muse, varscan2
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs1356395055; called by muse, mutect2, varscan2
- SYT14 | c.*976G>A | 3'UTR (SNP) | VAF 5/25 reads (20%) | catalogued as rs902313441; called by muse, mutect2, varscan2
- TBX1 | c.1009+535C>T | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- TMEM67 | chr8:93819062 A>C | 3'Flank (SNP) | VAF 17/259 reads (7%) | called by muse, mutect2
- TUBGCP2 | c.616+586A>G | Intron (SNP) | VAF 9/64 reads (14%) | called by mutect2, varscan2
- ZNF131 | chr5:43175494 C>G | 3'Flank (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
